Somatic mutation profile of tumor specimen TARGET-10-PATZFF-09A (aliquot TARGET-10-PATZFF-09A-01D) from TARGET case TARGET-10-PATZFF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.7 years (3,906 days).
Specimen TARGET-10-PATZFF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 526e2bff-4dd2-4aad-87f4-4282a2520126.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATZFF-10A (Blood Derived Normal), aliquot TARGET-10-PATZFF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c496b5a-ee5d-4062-a546-f80a6b11e5db

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Frame Shift Ins 3, Nonsense Mutation 2, Splice Region 2, Intron 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADH1B | c.1103G>T p.S368I | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1348285202, COSV59295571, COSV59296239; called by muse, mutect2, varscan2
- AHDC1 | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as rs753277572, COSV55937357; called by muse, mutect2, varscan2
- DHX15 | c.2155G>T p.V719F | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100391809, COSV61026064; called by muse, mutect2, varscan2
- EPPK1 | c.6268C>G p.R2090G | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV101599931, COSV73260944, COSV73262304; called by muse, mutect2, varscan2
- ITIH5 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200420644, COSV56900299; called by muse, mutect2, varscan2
- KCND3 | c.1501C>T p.R501* | Nonsense Mutation (SNP) | VAF 28/49 reads (57%) | catalogued as rs752361842, COSV56176991; called by muse, mutect2, varscan2
- KMT2D | c.15289C>T p.R5097* | Nonsense Mutation (SNP) | VAF 20/49 reads (41%) | catalogued as COSV56421006; called by muse, mutect2, varscan2
- NOTCH1 | c.7406_7410dup p.S2471Hfs*8 | Frame Shift Ins (INS) | VAF 6/18 reads (33%) | catalogued as COSV53047176; called by mutect2, varscan2
- OR51V1 | c.691G>T p.V231F | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV58314439; called by muse, mutect2, varscan2
- PCDHA6 | c.785T>C p.I262T | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.039); catalogued as rs1554131616, COSV65350407; called by muse, mutect2, varscan2
- PCDHA7 | c.1096G>C p.G366R | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV65342685; called by muse, mutect2, varscan2
- RBX1 | c.229-6T>C | Splice Region (SNP) | VAF 26/53 reads (49%) | catalogued as COSV53429765; called by muse, mutect2, varscan2
- RPL10 | c.292C>A p.R98S | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV50009981, COSV50010241; called by muse, mutect2, varscan2
- SEMA3E | c.1399T>G p.Y467D | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.824); catalogued as COSV57082861; called by muse, mutect2, varscan2
- TEP1 | c.5893G>A p.G1965S | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as rs138288297; called by muse, mutect2, varscan2
- WASF2 | c.1405G>A p.V469M | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71005016; called by muse, mutect2, varscan2
- BCL11B | c.363dup p.D122Rfs*4 | Frame Shift Ins (INS) | VAF 5/16 reads (31%) | called by mutect2, varscan2
- DNAJB12 | c.1143_1144insACCTGGACCC p.D382Tfs*136 (on ENST00000338820; = p.D348Tfs*59 on NM_017626.6 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- SSPOP | n.7280+4A>T | Splice Region (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- IGSF3 | c.1065C>T p.S355= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs751143665, COSV59585922; called by muse, mutect2, varscan2
- NPY1R | c.846T>C p.F282= | Silent (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- PRPF8 | c.1173A>C p.T391= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- MAGEA5 | n.68T>A | RNA (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- SEC31B | c.2651-12G>T | Intron (SNP) | VAF 13/27 reads (48%) | catalogued as rs778208381; called by muse, mutect2, varscan2
- STRA6 | chr15:74209458 G>A | 5'Flank (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
